Somatic mutation profile of tumor specimen TARGET-10-PATDLG-09A (aliquot TARGET-10-PATDLG-09A-01D) from TARGET case TARGET-10-PATDLG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.8 years (4,306 days).
Specimen TARGET-10-PATDLG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50bf8def-ebbd-4f83-b02f-0f60c5d96f99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATDLG-10A (Blood Derived Normal), aliquot TARGET-10-PATDLG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa030d0f-d3eb-4300-93fe-24460363a2e2

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 4, Silent 2, Frame Shift Ins 2, 5'UTR 1, In Frame Del 1, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 29/85 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATAD1 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs780964486, COSV57755756; called by muse, mutect2, varscan2
- DNM2 | c.1357C>T p.R453* | Nonsense Mutation (SNP) | VAF 34/79 reads (43%) | catalogued as COSV58957081; called by muse, mutect2, varscan2
- GREB1L | c.1918G>A p.D640N | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52548519; called by muse, mutect2, varscan2
- JRK | c.1236_1238del p.N412del | In Frame Del (DEL) | VAF 46/117 reads (39%) | catalogued as rs1228734332; called by pindel, varscan2
- NDOR1 | c.1415G>A p.R472H (on ENST00000371521 / NM_001144026.3; = p.R465H on NM_014434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775944305, COSV61286284; called by muse, mutect2, varscan2
- NELFE | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.558); catalogued as rs775691868, COSV64810105; called by muse, mutect2, varscan2
- NOTCH1 | c.4847T>A p.I1616N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53028112; called by muse, mutect2, varscan2
- PEMT | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV55129957; called by muse, mutect2, varscan2
- ROR2 | c.2203C>T p.R735W | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs761169064, COSV65216444; called by muse, mutect2, varscan2
- UNC13C | c.5317C>A p.L1773M | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52843275; called by muse, mutect2, varscan2
- ENTPD8 | c.1259G>A p.S420N (on ENST00000371506 / NM_001033113.2; = p.S383N on NM_198585.3) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.05); called by muse, varscan2
- EPOR | c.1275dup p.Y426Vfs*19 | Frame Shift Ins (INS) | VAF 10/112 reads (9%) | called by mutect2, pindel
- NOTCH1 | c.4356_4357insCCCGCGACCGTC p.P1452_E1453insPATV | In Frame Ins (INS) | VAF 6/48 reads (13%) | called by mutect2, pindel
- SPRY2 | c.491dup p.P165Afs*15 | Frame Shift Ins (INS) | VAF 36/99 reads (36%) | called by mutect2, pindel, varscan2
- KLHDC9 | c.840C>A p.T280= | Silent (SNP) | VAF 31/119 reads (26%) | called by muse, mutect2, varscan2
- NCOR2 | c.636G>A p.K212= | Silent (SNP) | VAF 55/118 reads (47%) | called by muse, mutect2, varscan2
- CLCN6 | c.2529+54G>A | Intron (SNP) | VAF 144/299 reads (48%) | catalogued as rs767438514, COSV56738561; called by muse, mutect2, varscan2
- IGFN1 | c.1242-1418G>A | Intron (SNP) | VAF 58/132 reads (44%) | catalogued as COSV55165767; called by muse, mutect2, varscan2
- MYH14 | c.5837+152G>T | Intron (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- SLCO1C1 | c.1916+67C>T | Intron (SNP) | VAF 66/160 reads (41%) | catalogued as rs188703518; called by muse, mutect2, varscan2
- UGT3A1 | c.-70G>A | 5'UTR (SNP) | VAF 41/110 reads (37%) | catalogued as COSV57095545; called by muse, mutect2, varscan2
